Somatic mutation profile of tumor specimen 0DPBGV from CCDI case PBCDDH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 4.3 years (1,583 days).
Specimen 0DPBGV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77f6d25f-a67a-4d8b-b110-cc6beb8357bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPBFB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/806e1e73-ad16-42b6-ae29-796ba008a191

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TPM3 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 102/564 reads (18%) | catalogued as rs727504181; ClinVar: pathogenic; called by muse, varscan2
- ENAM | c.3226G>A p.D1076N | Missense Mutation (SNP) | VAF 166/809 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs140345705, COSV68535392; called by muse, varscan2
- IL31RA | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 168/832 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs747291521, COSV51680773, COSV99763023; called by muse, varscan2
- DIAPH3 | c.1820G>A p.S607N (on ENST00000400324 / NM_001042517.2; = p.S344N on NM_030932.3) | Missense Mutation (SNP) | VAF 106/374 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, varscan2
- NETO2 | c.1412T>C p.M471T | Missense Mutation (SNP) | VAF 316/1162 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.083); called by muse, varscan2
- GHRHR | c.756G>T p.L252= | Silent (SNP) | VAF 63/248 reads (25%) | called by muse, varscan2
